Somatic mutation profile of tumor specimen TCGA-EE-A3AD-06A (aliquot TCGA-EE-A3AD-06A-11D-A196-08) from TCGA case TCGA-EE-A3AD, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 50.6 years (18,491 days).
Specimen TCGA-EE-A3AD-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fcdc81a-e69f-4b8a-a63b-af01cfc889e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A3AD-10A (Blood Derived Normal), aliquot TCGA-EE-A3AD-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ad26e4e-0d35-4339-8f66-7feeb2d94134

The open-access MAF lists 518 somatic variants for this specimen: 323 protein-altering or splice-affecting, 186 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 289, Silent 186, Nonsense Mutation 19, Intron 5, Splice Site 5, Splice Region 5, Frame Shift Del 4, RNA 3, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/40 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDK4 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 31/42 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as rs104894340, CM980320, COSV56983700, COSV56984378; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PAK5 | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 42/90 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs769939031, COSV62021293; called by mutect2, varscan2
- TACC3 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 44/76 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as COSV57603049; called by muse, mutect2, varscan2
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 39/96 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.264); catalogued as rs781199262, COSV62929944; called by mutect2, varscan2
- ABCC3 | c.222+1G>A p.X74_splice | Splice Site (SNP) | VAF 32/62 reads (52%) | catalogued as COSV53319957; called by muse, varscan2
- ABCF3 | c.1514A>G p.H505R | Missense Mutation (SNP) | VAF 88/168 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1436772866, COSV53051824; called by muse, varscan2
- ABHD15 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56195158; called by muse, mutect2, varscan2
- ACSM1 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54634744; called by muse, mutect2, varscan2
- ACSM2A | c.1336G>A p.D446N (on ENST00000219054; = p.D367N on NM_001308169.2) | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54583929; called by muse, mutect2, varscan2
- ACSM2B | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61657466; called by muse, mutect2, varscan2
- ADAMTS14 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV64601313; called by muse, mutect2, varscan2
- ADAMTS20 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 161/262 reads (61%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67130027; called by muse, mutect2, varscan2
- ADCY8 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 80/103 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV53900356; called by muse, mutect2, varscan2
- ADGRE1 | c.2489C>T p.T830I | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV99165123; called by muse, mutect2, varscan2
- ADGRF4 | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 256/382 reads (67%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.513); catalogued as rs200623239, COSV51949975; called by muse, mutect2, varscan2
- ADGRV1 | c.4555G>A p.G1519R | Missense Mutation (SNP) | VAF 66/97 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67979912; called by muse, mutect2, varscan2
- ADK | c.241G>A p.G81S (on ENST00000286621; = p.G64S on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54203684; called by muse, mutect2, varscan2
- ADSL | c.1324C>T p.H442Y | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV53407370; called by mutect2, varscan2
- AFM | c.1079G>A p.R360K | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56919771; called by muse, mutect2, varscan2
- AKR1D1 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 32/33 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773852919, COSV54337110, COSV99653217; called by muse, mutect2, varscan2
- ALDH6A1 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63245885; called by muse, mutect2, varscan2
- AMBRA1 | c.3823A>G p.N1275D (on ENST00000458649 / NM_001367468.1; = p.N1185D on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV54052354; called by muse, mutect2, varscan2
- ANK3 | c.3108G>A p.M1036I (on ENST00000280772 / NM_001320874.2; = p.M170I on NM_001149.3) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs557148326, COSV55053068; called by muse, mutect2, varscan2
- AP3B2 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV55605940; called by mutect2, varscan2
- APOB | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 133/154 reads (86%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs143959032, COSV51931688; called by muse, mutect2, varscan2
- APOH | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV52772137; called by muse, mutect2, varscan2
- ARHGAP21 | c.4631C>A p.S1544Y | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV57604627; called by mutect2, varscan2
- ASTN1 | c.3706C>T p.L1236F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV62494766; called by muse, mutect2, varscan2
- ATM | c.7867C>T p.L2623F | Missense Mutation (SNP) | VAF 29/30 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53737914; called by muse, mutect2, varscan2
- ATP13A4 | c.3542G>A p.G1181E | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV61319092; called by muse, mutect2, varscan2
- ATP13A5 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1340327629, COSV60865060; called by muse, mutect2, varscan2
- ATRNL1 | c.2513C>T p.P838L | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs145512153, COSV58099327; called by muse, mutect2, varscan2
- ATXN2 | c.3685C>T p.H1229Y (on ENST00000550104; = p.H1069Y on NM_002973.4) | Missense Mutation (SNP) | VAF 149/219 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57982584; called by muse, mutect2, varscan2
- B3GAT2 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs752630184, COSV57637738; called by muse, mutect2, varscan2
- BACH1 | c.2081G>A p.R694Q | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs377002114; called by muse, mutect2, varscan2
- BPIFB3 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64957161; called by muse, mutect2, varscan2
- BSN | c.5035C>T p.L1679F | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs1327955853, COSV99607709; called by muse, mutect2, varscan2
- C10orf71 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV60506643; called by mutect2, varscan2
- C16orf78 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1252336191, COSV54555752; called by mutect2, varscan2
- C2CD3 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs758536690, COSV58092147; called by muse, mutect2, varscan2
- C3 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as rs1306521442, COSV55571492; called by muse, mutect2, varscan2
- C5orf22 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 66/68 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57598121; called by muse, mutect2, varscan2
- C8A | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 46/70 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as COSV63483374; called by muse, mutect2, varscan2
- CA10 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53345310; called by muse, mutect2, varscan2
- CA9 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV65675473; called by muse, mutect2, varscan2
- CACNB2 | c.820C>T p.P274S (on ENST00000324631 / NM_201596.3; = p.P219S on NM_000724.4) | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56619669; called by muse, mutect2, varscan2
- CAMK2A | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.906); catalogued as rs1445974036, COSV62245965; called by muse, mutect2, varscan2
- CCDC78 | c.270C>T p.I90= | Splice Region (SNP) | VAF 15/32 reads (47%) | catalogued as rs1413532360, COSV52401672; called by muse, mutect2, varscan2
- CD200R1 | c.415G>A p.G139R (on ENST00000471858 / NM_170780.3; = p.G162R on NM_138806.4) | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179235507, COSV55600086; called by muse, mutect2, varscan2
- CD244 | c.1037G>A p.G346E (on ENST00000368033 / NM_001166663.2; = p.G341E on NM_016382.4) | Missense Mutation (SNP) | VAF 81/162 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV54433378; called by muse, mutect2, varscan2
- CD53 | c.194T>A p.V65E | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54760887; called by muse, mutect2, varscan2
- CDH10 | c.149A>G p.H50R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV52577573; called by muse, mutect2, varscan2
- CEACAM19 | c.100C>T p.L34F | Missense Mutation (SNP) | VAF 68/74 reads (92%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.458); catalogued as COSV62551928; called by muse, varscan2
- CELF5 | c.395G>A p.R132K | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1385429519, COSV53011221; called by muse, mutect2, varscan2
- CEP104 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 89/158 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139901107, COSV65512136; called by mutect2, varscan2
- CHPF2 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 81/84 reads (96%) | SIFT tolerated (0.09); PolyPhen benign (0.381); catalogued as COSV50390364; called by muse, mutect2, varscan2
- CHRDL1 | c.391C>T p.R131W (on ENST00000372045; = p.R137W on NM_145234.4) | Missense Mutation (SNP) | VAF 136/142 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749956744, COSV54324410; called by muse, varscan2
- CHST5 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1389703147, COSV60338479; called by mutect2, varscan2
- CLCN3 | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV100641629; called by muse, mutect2, varscan2
- CLEC5A | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs1197523757, COSV69397002; called by muse, mutect2, varscan2
- CMYA5 | c.7630C>T p.Q2544* | Nonsense Mutation (SNP) | VAF 7/10 reads (70%) | catalogued as COSV71405291; called by mutect2, varscan2
- CNGA1 | c.1185G>A p.M395I | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV62053897; called by muse, mutect2, varscan2
- CNGB1 | c.3273G>T p.K1091N | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV51899818; called by mutect2, varscan2
- CNOT1 | c.3386G>A p.W1129* | Nonsense Mutation (SNP) | VAF 30/73 reads (41%) | catalogued as COSV55315160; called by muse, mutect2, varscan2
- COASY | c.1093G>A p.G365S | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55898239; called by muse, mutect2, varscan2
- COL11A2 | c.1256C>T p.P419L (on ENST00000341947 / NM_080680.3; = p.P312L on NM_080679.2) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV59495793; called by muse, mutect2, varscan2
- COL14A1 | c.4477G>A p.E1493K | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as COSV52852002; called by mutect2, varscan2
- COL1A2 | c.2081G>A p.G694D | Missense Mutation (SNP) | VAF 44/48 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51956300; called by muse, varscan2
- COL25A1 | c.1345G>A p.G449S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67649102; called by muse, mutect2, varscan2
- COL27A1 | c.2038C>T p.L680F | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as rs925527457, COSV61924788; called by muse, varscan2
- COL5A3 | c.2633G>A p.G878E | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53409223; called by muse, varscan2
- CPLX4 | c.448A>C p.K150Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV55313431; called by muse, mutect2, varscan2
- CPSF2 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV54097860; called by muse, mutect2, varscan2
- CRACD | c.3008C>T p.P1003L | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs1344458249, COSV51719285, COSV99948927; called by muse, mutect2, varscan2
- CRNN | c.1286G>A p.G429E | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs1029015590, COSV55121574; called by muse, mutect2, varscan2
- CSK | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54973451; called by muse, mutect2, varscan2
- CTDP1 | c.2405C>T p.P802L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV50002351; called by muse, mutect2
- CX3CL1 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs1347011692, COSV50055693; called by muse, mutect2, varscan2
- CXXC1 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV53273412; called by mutect2, varscan2
- CYLC2 | c.574G>C p.D192H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as rs778454808, COSV66336095, COSV66337159; called by muse, mutect2, varscan2
- CYP4A11 | c.1529C>T p.P510L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as rs564367884, COSV60223019, COSV60223890; called by mutect2, varscan2
- CYP4B1 | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as rs375759162; called by muse, mutect2, varscan2
- CYP4F3 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs774751788, COSV99657972; called by mutect2, varscan2
- DAB1 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV100976206; called by mutect2, varscan2
- DAGLA | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57195351; called by muse, varscan2
- DBH | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV55040412; called by muse, mutect2, varscan2
- DENND5B | c.1826C>T p.S609F | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.669); catalogued as COSV60901790, COSV60907657; called by muse, mutect2, varscan2
- DIP2B | c.526A>G p.N176D | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV56582051; called by muse, mutect2, varscan2
- DNAH5 | c.870G>A p.W290* | Nonsense Mutation (SNP) | VAF 309/403 reads (77%) | catalogued as rs916132038, COSV54218105; called by muse, mutect2, varscan2
- DOCK10 | c.6065C>T p.S2022L | Missense Mutation (SNP) | VAF 62/68 reads (91%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV51352728; called by muse, mutect2, varscan2
- DPYD | c.2365C>T p.P789S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.798); catalogued as rs267598785, COSV64591183; called by muse, mutect2
- DPYSL2 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs774132967, COSV60782084, COSV60784505; called by mutect2, varscan2
- DSC1 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57141474, COSV99937583; called by mutect2, varscan2
- DSC2 | c.1307G>A p.G436D | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV51863478; called by muse, varscan2
- DUSP15 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs377341994; called by muse, mutect2, varscan2
- DYDC2 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1554848062, COSV55471697; called by muse, mutect2, varscan2
- EFCAB6 | c.3284G>A p.G1095E | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); catalogued as COSV53061492; called by muse, varscan2
- EGF | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs144013010, COSV54477656; called by muse, mutect2, varscan2
- EGFR | c.1722G>A p.R574= | Splice Region (SNP) | VAF 52/154 reads (34%) | catalogued as COSV51790717; called by muse, varscan2
- EIF6 | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV65582725; called by muse, mutect2, varscan2
- ELMO1 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs774208030, COSV60301623; called by muse, mutect2, varscan2
- ERLEC1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT tolerated (0.59); PolyPhen benign (0.018); catalogued as COSV99482907; called by muse, mutect2, varscan2
- F8 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 72/72 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as CM003811, COSV100811383; called by muse, mutect2, varscan2
- F9 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV54379761; called by mutect2, varscan2
- FADS3 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53877985; called by muse, mutect2, varscan2
- FAM135B | c.3574G>A p.D1192N | Missense Mutation (SNP) | VAF 65/89 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52717937; called by muse, mutect2, varscan2
- FAM13C | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs781708491, COSV53243827; called by mutect2, varscan2
- FAM71A | c.1265A>T p.E422V | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs201149435, COSV54235340; called by mutect2, varscan2
- FAM83B | c.2158G>A p.D720N | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV60921229; called by muse, mutect2, varscan2
- FAT3 | c.5548C>T p.H1850Y | Missense Mutation (SNP) | VAF 70/78 reads (90%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV53093612; called by mutect2, varscan2
- FAT4 | c.13109C>T p.S4370F | Missense Mutation (SNP) | VAF 156/279 reads (56%) | SIFT tolerated (0.68); PolyPhen benign (0.085); catalogued as rs762418523, COSV58679798; called by muse, mutect2, varscan2
- FAT4 | c.14796G>A p.W4932* | Nonsense Mutation (SNP) | VAF 42/74 reads (57%) | catalogued as COSV58679814; called by muse, mutect2, varscan2
- FCRL3 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.229); catalogued as rs559562792, COSV100943629, COSV63840816; called by muse, mutect2, varscan2
- FER1L6 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 86/138 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67550060; called by muse, mutect2, varscan2
- FEZ1 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 53/62 reads (85%) | catalogued as COSV54027907; called by muse, mutect2, varscan2
- FKBP11 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1185599350, COSV56740333; called by muse, mutect2, varscan2
- FOXJ1 | c.508C>G p.R170G | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53943307; called by muse, mutect2, varscan2
- FRAS1 | c.1693T>G p.C565G | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53603711; called by muse, varscan2
- GCLC | c.1091G>A p.G364D (on ENST00000643939; = p.G362D on NM_001498.4) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.62); catalogued as COSV99988421; called by muse, mutect2, varscan2
- GDE1 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 70/136 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs752254773, COSV62059338; called by muse, varscan2
- GLB1L3 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 32/32 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66281284; called by muse, mutect2, varscan2
- GLIS3 | c.1252G>A p.G418S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60927471; called by muse, mutect2, varscan2
- GLRA1 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 45/60 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51009533; called by muse, varscan2
- GLYAT | c.684G>A p.M228I | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs373776314; called by mutect2, varscan2
- GRB2 | c.19del p.Y7Mfs*11 | Frame Shift Del (DEL) | VAF 79/227 reads (35%) | catalogued as COSV57305356; called by mutect2, pindel, varscan2
- GRIK5 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 31/32 reads (97%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV53477372; called by muse, mutect2, varscan2
- GRM8 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT tolerated (0.15); PolyPhen benign (0.119); catalogued as COSV58818698; called by muse, varscan2
- GRM8 | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 42/44 reads (95%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV58818705; called by muse, varscan2
- GSDMA | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.89); PolyPhen benign (0.029); catalogued as rs1453613290, COSV56974409; called by muse, mutect2, varscan2
- GUCA1C | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs1265768088, COSV51712957; called by mutect2, varscan2
- HAL | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as rs367677601; called by mutect2, varscan2
- HBZ | c.80C>T p.T27I | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as COSV53316654; called by muse, mutect2, varscan2
- HCN4 | c.1385G>A p.G462E | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs146714274; called by muse, mutect2, varscan2
- HEATR5A | c.5218C>T p.P1740S | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV66339757; called by muse, mutect2, varscan2
- HERC2 | c.2419C>T p.R807W | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1193330360, COSV55318403; called by muse, mutect2, varscan2
- HNRNPU | c.1877G>A p.R626K (on ENST00000283179; = p.R688K on NM_004501.3) | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.35); catalogued as COSV51690552, COSV99310783; called by muse, varscan2
- HPCAL4 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as COSV65716186; called by muse, mutect2, varscan2
- HYDIN | c.9401C>T p.P3134L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59254733; called by muse, mutect2, varscan2
- IGFLR1 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 17/17 reads (100%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV53074508; called by muse, mutect2, varscan2
- IGSF9 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1232557105, COSV63639661; called by muse, mutect2, varscan2
- IKBKB | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV60596969; called by muse, mutect2, varscan2
- IL6ST | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV61140783; called by muse, mutect2, varscan2
- INTS2 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1433760940, COSV52152071, COSV99248010; called by muse, mutect2, varscan2
- IQCN | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV66573577; called by muse, mutect2, varscan2
- ITGAM | c.1636G>A p.E546K (on ENST00000648685 / NM_001145808.2; = p.E545K on NM_000632.4) | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54936152; called by muse, mutect2, varscan2
- ITPR1 | c.2434C>T p.P812S (on ENST00000354582; = p.P797S on NM_002222.7) | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV56977241; called by muse, mutect2, varscan2
- ITPR1 | c.3170G>A p.G1057D (on ENST00000354582; = p.G1042D on NM_002222.7) | Missense Mutation (SNP) | VAF 82/179 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV56977267; called by muse, mutect2, varscan2
- ITPRIP | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as rs200009556; called by muse, mutect2, varscan2
- JAM3 | c.544A>T p.T182S | Missense Mutation (SNP) | VAF 27/28 reads (96%) | SIFT tolerated (0.67); PolyPhen benign (0.08); catalogued as COSV54452057; called by muse, mutect2, varscan2
- KALRN | c.8338G>A p.V2780I (on ENST00000360013 / NM_001024660.4; = p.V1083I on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.981); catalogued as rs200993632, COSV52254547; called by muse, varscan2
- KBTBD8 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 52/103 reads (50%) | catalogued as COSV55128018; called by mutect2, varscan2
- KCNB1 | c.2447C>T p.S816F | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.081); catalogued as COSV65567341; called by muse, mutect2, varscan2
- KCNB2 | c.1893G>A p.M631I | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); catalogued as COSV73049296; called by mutect2, varscan2
- KCNB2 | c.1895A>T p.K632M | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.797); catalogued as COSV73049755; called by mutect2, varscan2
- KCNJ16 | c.1249C>T p.Q417* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV52252396; called by muse, mutect2, varscan2
- KCTD13 | c.507C>T p.P169= | Splice Region (SNP) | VAF 21/52 reads (40%) | catalogued as rs376560193, COSV58159807; called by muse, mutect2, varscan2
- KDM4A | c.499A>G p.T167A | Missense Mutation (SNP) | VAF 52/88 reads (59%) | SIFT tolerated (0.41); PolyPhen benign (0.386); catalogued as COSV64958885, COSV64959268; called by muse, mutect2, varscan2
- KIAA0319L | c.2248C>T p.L750F | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57844460; called by muse, mutect2, varscan2
- KIR2DL1 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 70/73 reads (96%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.499); catalogued as COSV52408804; called by muse, mutect2, varscan2
- KRT6A | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV58104225; called by muse, mutect2, varscan2
- LAMC1 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 110/274 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs751263119, COSV99279251; called by mutect2, varscan2
- LBP | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 90/187 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.53); catalogued as COSV54139846; called by muse, mutect2, varscan2
- LILRA4 | c.128A>G p.N43S | Missense Mutation (SNP) | VAF 49/51 reads (96%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52491508, COSV52493715; called by muse, mutect2, varscan2
- LIPE | c.683G>A p.W228* | Nonsense Mutation (SNP) | VAF 81/84 reads (96%) | catalogued as COSV54922291; called by muse, mutect2, varscan2
- LNPEP | c.2395C>T p.L799F | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.173); catalogued as COSV51477409; called by muse, mutect2, varscan2
- LRIF1 | c.1513C>T p.Q505* | Nonsense Mutation (SNP) | VAF 37/112 reads (33%) | catalogued as COSV100870769, COSV63897116; called by muse, mutect2, varscan2
- LRIT3 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59984596; called by muse, mutect2, varscan2
- LRRIQ3 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs764577654, COSV63041977; called by muse, varscan2
- LTBP2 | c.4493C>T p.P1498L | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.087); catalogued as rs766870197, COSV56206956; called by muse, varscan2
- LY75 | c.4451C>T p.S1484F | Missense Mutation (SNP) | VAF 72/76 reads (95%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV55104359; called by muse, mutect2, varscan2
- MAGEA12 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 83/86 reads (97%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV63294295; called by muse, mutect2, varscan2
- MAGEC3 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 126/130 reads (97%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as COSV53578731; called by mutect2, varscan2
- MC2R | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs753089914, COSV59617773; called by mutect2, varscan2
- MECOM | c.2468C>T p.S823L (on ENST00000468789 / NM_001105078.4; = p.S1011L on NM_004991.4) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs540158912, COSV52961560; called by mutect2, varscan2
- MECOM | c.1679G>A p.R560Q (on ENST00000468789 / NM_001105078.4; = p.R748Q on NM_004991.4) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.778); catalogued as rs755819303, COSV52958497; called by mutect2, varscan2
- MED16 | c.1962G>T p.M654I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99515266; called by muse, mutect2, varscan2
- MEFV | c.155A>G p.K52R | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.063); catalogued as COSV54820720; called by muse, varscan2
- MINDY3 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as rs776784319, COSV53219143; called by muse, mutect2
- MMP2 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1351967941, COSV54600497; called by mutect2, varscan2
- MRTFB | c.2989C>T p.P997S (on ENST00000571589 / NM_001365412.2; = p.P947S on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV57957275; called by muse, mutect2, varscan2
- MSLNL | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.388); catalogued as COSV53500956; called by muse, mutect2, varscan2
- MUC17 | c.12564G>A p.M4188I | Missense Mutation (SNP) | VAF 59/66 reads (89%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1385711958, COSV60285710; called by muse, mutect2, varscan2
- MUC5AC | c.13709G>A p.S4570N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.17); catalogued as COSV100611365; called by muse, mutect2, varscan2
- MUCL1 | c.237G>A p.W79* | Nonsense Mutation (SNP) | VAF 11/17 reads (65%) | catalogued as rs766274450, COSV58193047; called by muse, mutect2, varscan2
- MXRA5 | c.6952G>A p.E2318K | Missense Mutation (SNP) | VAF 68/70 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54231712; called by muse, mutect2, varscan2
- MYCBPAP | c.2291G>A p.C764Y | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV100087886; called by muse, mutect2, varscan2
- MYH3 | c.4010C>T p.S1337F | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs769977048, COSV56863522; called by muse, varscan2
- MYOF | c.1628C>T p.T543I | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs780055290, COSV63700971; called by muse, mutect2, varscan2
- MYOF | c.1627A>T p.T543S | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.471); catalogued as COSV100825440; called by muse, mutect2, varscan2
- NCOR2 | c.3166C>T p.P1056S | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.736); catalogued as COSV62296528; called by muse, varscan2
- NEBL | c.440A>C p.E147A | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV65799608; called by muse, mutect2, varscan2
- NETO1 | c.83-1G>A p.X28_splice | Splice Site (SNP) | VAF 29/47 reads (62%) | catalogued as rs867480089; called by mutect2, varscan2
- NKD2 | c.201G>A p.Q67= | Splice Region (SNP) | VAF 19/66 reads (29%) | catalogued as COSV56890936; called by muse, mutect2, varscan2
- NLRP14 | c.2918G>A p.G973E | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55065964; called by muse, mutect2, varscan2
- NOS3 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 28/28 reads (100%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as COSV52488635; called by muse, mutect2, varscan2
- NPHP3 | c.1673C>T p.S558F | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV58629398; called by muse, mutect2, varscan2
- NRG1 | c.1237G>A p.D413N (on ENST00000405005 / NM_013964.5; = p.D418N on NM_013956.5) | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV55155082; called by mutect2, varscan2
- NTRK1 | c.1019C>T p.T340I | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV62323144; called by muse, mutect2, varscan2
- NXF3 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 57/57 reads (100%) | catalogued as rs755460265, COSV67703268; called by mutect2, varscan2
- NYNRIN | c.3659C>T p.S1220F | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV66841974; called by muse, mutect2, varscan2
- OBSCN | c.17933C>T p.S5978L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.139); catalogued as rs368401676, COSV99485466; called by mutect2, varscan2
- OLFML2B | c.269A>G p.Q90R | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54195618; called by muse, varscan2
- OR10C1 | c.632C>T p.P211L (on ENST00000622521; = p.P209L on NM_013941.3) | Missense Mutation (SNP) | VAF 136/307 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV65822555; called by muse, mutect2, varscan2
- OR10G4 | c.905G>A p.R302K | Missense Mutation (SNP) | VAF 35/36 reads (97%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV57977317; called by muse, mutect2, varscan2
- OR14C36 | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs760870864, COSV58600955; called by muse, mutect2, varscan2
- OR2B6 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139328462, COSV55128769; called by muse, mutect2, varscan2
- OR2M5 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as COSV100822880, COSV63546061; called by mutect2, varscan2
- OR4C6 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs868600897, COSV58602718; called by muse, mutect2, varscan2
- OR4M1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 46/77 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1340499119, COSV60060517; called by muse, varscan2
- OR52M1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs267602886, COSV64172059; called by mutect2, varscan2
- OR6C4 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); catalogued as COSV67792883; called by muse, mutect2, varscan2
- OSGIN2 | c.1202A>G p.K401R | Missense Mutation (SNP) | VAF 79/120 reads (66%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV52408027; called by muse, mutect2, varscan2
- OVCH2 | c.1634A>C p.K545T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.098); catalogued as COSV71952776; called by muse, varscan2
- PADI3 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV64934384; called by muse, mutect2, varscan2
- PCDHB10 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554284401, COSV99503945; called by muse, varscan2
- PCDHB16 | c.1280G>A p.G427E | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53360969; called by muse, mutect2, varscan2
- PCDHB9 | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.099); catalogued as COSV53375009; called by muse, mutect2, varscan2
- PCLO | c.9544C>T p.P3182S | Missense Mutation (SNP) | VAF 19/19 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV61627990; called by muse, mutect2, varscan2
- PCNT | c.9934G>T p.V3312L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV64027110; called by muse, mutect2, varscan2
- PCSK2 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs1568616893, COSV52730533; called by muse, mutect2, varscan2
- PCSK5 | c.4987G>A p.G1663R | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.547); catalogued as rs1236203444, COSV70448931; called by muse, mutect2, varscan2
- PDE6C | c.1658G>A p.R553K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); catalogued as COSV65115490; called by mutect2, varscan2
- PDE9A | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 109/262 reads (42%) | catalogued as rs201357375, COSV52324362; called by mutect2, varscan2
- PDGFC | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 57/85 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1285168954, COSV56847587; called by muse, mutect2, varscan2
- PGBD4 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated (0.85); PolyPhen benign (0.042); catalogued as COSV56627481; called by mutect2, varscan2
- PHRF1 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as rs367813947, COSV52762193; called by mutect2, varscan2
- PIGG | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781997463, COSV56317498; ClinVar: uncertain significance; called by mutect2, varscan2
- PIGZ | c.1702C>T p.L568F | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs370198315; called by muse, mutect2, varscan2
- PLB1 | c.1434-1G>A p.X478_splice | Splice Site (SNP) | VAF 25/29 reads (86%) | catalogued as COSV59823013; called by muse, mutect2, varscan2
- PLPP6 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV56304982; called by muse, mutect2, varscan2
- POLR2B | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 79/250 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58899803; called by muse, mutect2, varscan2
- POTEF | c.2170G>A p.D724N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.171); catalogued as rs761290085, COSV99051461; called by mutect2, varscan2
- PREX2 | c.2086C>T p.P696S | Missense Mutation (SNP) | VAF 73/111 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55763491; called by muse, varscan2
- PREX2 | c.3283G>A p.E1095K | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV55763507; called by muse, mutect2, varscan2
- PSMG1 | c.232A>C p.N78H | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV59000247; called by muse, mutect2, varscan2
- PTGER2 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV55418191; called by muse, mutect2, varscan2
- PTK7 | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 48/77 reads (62%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.896); catalogued as COSV57847937; called by muse, mutect2, varscan2
- PTPRB | c.4609C>T p.P1537S | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.658); catalogued as rs769664975, COSV54238519; called by muse, mutect2, varscan2
- PXDNL | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV62482717; called by muse, mutect2, varscan2
- RAB6B | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.619); catalogued as COSV53313024; called by muse, mutect2, varscan2
- RAPGEF2 | c.3361C>T p.P1121S | Missense Mutation (SNP) | VAF 71/112 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52426827; called by muse, varscan2
- RAPGEF5 | c.704G>A p.G235E (on ENST00000401957 / NM_001367602.2; = p.G538E on NM_012294.5) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.017); catalogued as rs753921639, COSV59778569; called by mutect2, varscan2
- RC3H2 | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV61799509; called by muse, mutect2, varscan2
- RERGL | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.602); catalogued as COSV57461547; called by muse, mutect2, varscan2
- RFPL3 | c.576G>A p.W192* (on ENST00000249007 / NM_001098535.1; = p.W163* on NM_006604.2) | Nonsense Mutation (SNP) | VAF 42/121 reads (35%) | catalogued as COSV50748399; called by muse, mutect2, varscan2
- RNF214 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 32/33 reads (97%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.281); catalogued as COSV56118381; called by muse, mutect2, varscan2
- ROBO2 | c.3803C>T p.P1268L | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV100163942, COSV59906499; called by muse, mutect2, varscan2
- RPTOR | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60806995; called by muse, mutect2, varscan2
- RTL3 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV58183841; called by mutect2, varscan2
- RUNDC3B | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 45/47 reads (96%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.917); catalogued as rs756808827, COSV55945690; called by muse, mutect2, varscan2
- S1PR1 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 43/58 reads (74%) | SIFT tolerated (0.11); PolyPhen benign (0.106); catalogued as rs1557708024, COSV59513012; called by muse, mutect2, varscan2
- SCFD2 | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as rs1432561326, COSV66370776; called by muse, mutect2, varscan2
- SCN10A | c.995C>A p.P332Q | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71860972; called by muse, varscan2
- SCN5A | c.3022C>T p.P1008S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs199473184, CM099709, COSV61121369; ClinVar: not provided; called by muse, mutect2, varscan2
- SERPINA10 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs267604109, COSV56228009; called by mutect2, varscan2
- SH3RF2 | c.922C>T p.L308F | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT tolerated (0.13); PolyPhen benign (0.314); catalogued as COSV63037186; called by muse, mutect2, varscan2
- SHPK | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV99843733; called by muse, mutect2, varscan2
- SIL1 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 47/66 reads (71%) | catalogued as COSV54530754; called by muse, mutect2, varscan2
- SLC12A3 | c.1761G>A p.W587* | Nonsense Mutation (SNP) | VAF 36/72 reads (50%) | catalogued as COSV52634114; called by muse, mutect2, varscan2
- SLC12A5 | c.2000G>A p.G667E (on ENST00000454036 / NM_001134771.2; = p.G644E on NM_020708.5) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54788614; called by muse, mutect2, varscan2
- SLC16A9 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1384884784, COSV68098728; called by muse, mutect2, varscan2
- SLC22A9 | c.1212G>A p.M404I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.05); catalogued as COSV54166785, COSV54168018; called by mutect2, varscan2
- SLC4A1 | c.1694G>A p.G565D | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as CM983772, COSV52259410; called by muse, varscan2
- SLC5A5 | c.1243-1G>A p.X415_splice | Splice Site (SNP) | VAF 41/66 reads (62%) | catalogued as COSV99714890; called by muse, mutect2, varscan2
- SLC5A5 | c.1243G>A p.G415S | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV99714894; called by muse, mutect2, varscan2
- SLC6A11 | c.1489T>A p.Y497N | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV54392351; called by muse, mutect2, varscan2
- SMCO3 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV53762502; called by muse, mutect2, varscan2
- SNRPB | c.328G>C p.A110P | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV60015341; called by muse, mutect2, varscan2
- SPATA31E1 | c.1988G>A p.R663K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.23); catalogued as COSV57790813; called by muse, varscan2
- SPRY3 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 60/66 reads (91%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV57142588; called by muse, varscan2
- STC1 | c.570G>A p.M190I | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV51688235; called by muse, mutect2, varscan2
- SVIL | c.4387G>C p.A1463P (on ENST00000355867 / NM_021738.3; = p.A1037P on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV63442385; called by muse, mutect2
- TBX10 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs148072042, COSV56875184, COSV56876669; called by muse, mutect2, varscan2
- TBX10 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV100039655; called by muse, mutect2, varscan2
- TDGF1 | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV56125689; called by muse, mutect2, varscan2
- TENM3 | c.1301A>G p.K434R | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (1); PolyPhen probably damaging (0.956); catalogued as COSV69304765; called by muse, varscan2
- TENT4A | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50095181; called by muse, mutect2, varscan2
- TEX13A | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 27/29 reads (93%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV61152080; called by muse, mutect2, varscan2
- TFDP2 | c.875C>T p.S292F (on ENST00000489671 / NM_001178139.2; = p.S232F on NM_006286.5) | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57706971; called by muse, mutect2, varscan2
- TH | c.1460C>T p.S487F (on ENST00000381178 / NM_199292.3; = p.S456F on NM_000360.4) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV51746435; called by muse, mutect2, varscan2
- TLR1 | c.607C>T p.H203Y | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs764901169, COSV58303948; called by muse, mutect2, varscan2
- TLR3 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 44/73 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV57168145; called by muse, mutect2, varscan2
- TMEM109 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 59/110 reads (54%) | catalogued as rs754913552, COSV50003870; called by muse, mutect2, varscan2
- TMEM161B | c.601T>C p.F201L | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.092); catalogued as rs1308100766, COSV56930519; called by muse, varscan2
- TPP1 | c.688-1G>C p.X230_splice | Splice Site (SNP) | VAF 31/82 reads (38%) | catalogued as COSV54993870; called by muse, mutect2, varscan2
- TPSD1 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs748932201, COSV52975034; called by muse, mutect2, varscan2
- TRAPPC1 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs778794020, COSV58050121; called by mutect2, varscan2
- TRAV12-1 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as rs775700428; called by muse, varscan2
- TRAV17 | c.239G>A p.R80K | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs776343166; called by muse, varscan2
- TRPV1 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.45); catalogued as COSV99439035; called by muse, mutect2, varscan2
- TXNRD2 | c.594C>T p.I198= | Splice Region (SNP) | VAF 22/49 reads (45%) | catalogued as rs745552753, COSV57631875; called by mutect2, varscan2
- UGT2A1 | c.632G>A p.R211K | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); catalogued as COSV54140233, COSV99684889; called by muse, mutect2, varscan2
- UGT2B15 | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 54/86 reads (63%) | catalogued as rs774308500, COSV57734038; called by muse, mutect2, varscan2
- USH2A | c.5837G>A p.R1946Q | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs193921072, COSV56356434, COSV56419910; called by mutect2, varscan2
- VPS13B | c.2057G>A p.R686Q | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as rs771633070, COSV100661329; called by mutect2, varscan2
- WDR49 | c.1586C>T p.P529L (on ENST00000308378 / NM_001366158.1; = p.P870L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV57706363, COSV57710486; called by muse, varscan2
- WIPF2 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV60273298; called by muse, mutect2, varscan2
- XPR1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV62555775; called by mutect2, varscan2
- ZBTB4 | c.2179C>T p.R727* | Nonsense Mutation (SNP) | VAF 29/57 reads (51%) | catalogued as rs1455015926, COSV100262965; called by mutect2, varscan2
- ZFAND4 | c.1820A>C p.E607A | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as COSV60858643; called by muse, mutect2, varscan2
- ZFHX3 | c.5329C>T p.L1777F | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.092); catalogued as COSV51715177; called by muse, varscan2
- ZFYVE28 | c.2567C>T p.P856L | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs541967359, COSV52109947; called by muse, varscan2
- ZNF274 | c.526C>T p.R176W (on ENST00000610905; = p.R71W on NM_016324.3) | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.544); catalogued as rs957632932; called by muse, mutect2, varscan2
- ZNF292 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.889); catalogued as COSV100370094; called by muse, mutect2, varscan2
- ZNF292 | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100370096; called by mutect2, varscan2
- ZNF317 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV99926958; called by muse, mutect2, varscan2
- ZNF317 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV99926961; called by muse, mutect2, varscan2
- ZNF319 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.782); catalogued as rs1202933959, COSV54621783; called by muse, mutect2, varscan2
- ZNF500 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as rs984182311, COSV54787827; called by muse, mutect2, varscan2
- ZNF680 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 34/35 reads (97%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV59014920; called by muse, mutect2, varscan2
- ZNF766 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 29/30 reads (97%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs746640811, COSV63009041; called by muse, mutect2, varscan2
- ZNF778 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV60601145; called by mutect2, varscan2
- ZNF780A | c.1399C>T p.H467Y | Missense Mutation (SNP) | VAF 38/42 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866070542, COSV61815116, COSV61815990; called by mutect2, varscan2
- ZPLD1 | c.1043A>C p.D348A (on ENST00000466937 / NM_001329788.1; = p.D364A on NM_175056.2) | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV60352972; called by muse, mutect2, varscan2
- ZSCAN30 | c.1430C>G p.T477R | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV54350496; called by muse, mutect2, varscan2
- CP | c.2349_2350del p.Y784Sfs*5 | Frame Shift Del (DEL) | VAF 36/89 reads (40%) | called by pindel, varscan2
- PATJ | c.518_520del p.A173del | In Frame Del (DEL) | VAF 27/125 reads (22%) | called by mutect2, pindel, varscan2
- PRAMEF19 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 79/276 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by mutect2, varscan2
- RBP3 | c.3035C>T p.P1012L | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC45A3 | c.72_76del p.T25Wfs*50 | Frame Shift Del (DEL) | VAF 56/164 reads (34%) | called by pindel, varscan2
- TMPRSS11B | c.784del p.Y262Ifs*35 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | called by mutect2, pindel, varscan2
- ABCA13 | c.10440G>T p.L3480= | Silent (SNP) | VAF 81/127 reads (64%) | catalogued as COSV71286066; called by muse, mutect2, varscan2
- ABCC3 | c.447C>T p.I149= | Silent (SNP) | VAF 54/106 reads (51%) | catalogued as rs1037736149, COSV53319978; called by mutect2, varscan2
- ABHD17B | c.829T>C p.L277= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV61007657; called by muse, mutect2, varscan2
- ACTN2 | c.2307G>A p.K769= | Silent (SNP) | VAF 40/160 reads (25%) | catalogued as COSV63974130; called by muse, mutect2, varscan2
- ADAM2 | c.2139G>A p.R713= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as rs267601919, COSV55858842; called by muse, mutect2, varscan2
- ADAMTS18 | c.2442C>T p.F814= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs1233973955, COSV51403819; called by mutect2, varscan2
- ADAMTS6 | c.1200C>T p.T400= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs1210596393, COSV66858797; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1230G>A p.E410= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV58442992; called by muse, mutect2, varscan2
- AHSA1 | c.465C>T p.L155= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV53631683; called by mutect2, varscan2
- AKAP6 | c.6321G>A p.G2107= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as rs1253997920, COSV55211036; called by muse, mutect2, varscan2
- ANK1 | c.3963C>T p.N1321= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV55879017; called by muse, mutect2, varscan2
- ANK2 | c.709T>C p.L237= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV52156150; called by muse, mutect2, varscan2
- AOX1 | c.321C>T p.A107= | Silent (SNP) | VAF 44/49 reads (90%) | catalogued as COSV65981088; called by muse, mutect2, varscan2
- AP1B1 | c.2502C>T p.L834= | Silent (SNP) | VAF 89/203 reads (44%) | catalogued as COSV58016673; called by muse, mutect2, varscan2
- ARL1 | c.297A>T p.R99= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV55370139; called by mutect2, varscan2
- ASCC3 | c.3807C>T p.I1269= | Silent (SNP) | VAF 30/32 reads (94%) | catalogued as COSV61227712; called by muse, mutect2, varscan2
- ASGR2 | c.582C>T p.S194= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as rs1183353643, COSV54689572; called by muse, mutect2, varscan2
- ASMTL | c.744C>T p.P248= | Silent (SNP) | VAF 50/99 reads (51%) | catalogued as COSV67243378; called by muse, mutect2, varscan2
- ASTN1 | c.3705C>T p.L1235= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100705841; called by muse, mutect2, varscan2
- ATP13A3 | c.498T>A p.V166= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV55463483; called by mutect2, varscan2
- ATP6V0D2 | c.741C>T p.L247= | Silent (SNP) | VAF 52/72 reads (72%) | catalogued as COSV53414282; called by muse, mutect2, varscan2
- BPI | c.318C>T p.G106= (on ENST00000262865; = p.G102= on NM_001725.3) | Silent (SNP) | VAF 54/110 reads (49%) | catalogued as COSV53405133; called by muse, varscan2
- BRAF | c.1920G>A p.V640= (on ENST00000288602 / NM_001374244.1; = p.V600= on NM_004333.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 38/39 reads (97%) | catalogued as COSV56107175, COSV56109586; called by muse, mutect2, varscan2
- BSN | c.1767G>A p.Q589= | Silent (SNP) | VAF 49/93 reads (53%) | catalogued as COSV56516014; called by muse, mutect2, varscan2
- BSN | c.5034C>T p.I1678= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV99607703; called by muse, mutect2, varscan2
- BTBD16 | c.31C>T p.L11= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV53262169; called by muse, mutect2, varscan2
- C7orf31 | c.1755C>T p.S585= | Silent (SNP) | VAF 42/134 reads (31%) | catalogued as COSV52216851; called by muse, mutect2, varscan2
- CACNA2D2 | c.1560G>A p.L520= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs865890448, COSV56562524; called by mutect2, varscan2
- CAMTA2 | c.1563C>T p.I521= | Silent (SNP) | VAF 64/154 reads (42%) | catalogued as COSV61834361; called by muse, mutect2, varscan2
- CASR | c.1680C>T p.F560= (on ENST00000490131; = p.F637= on NM_000388.4) | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as COSV56135643; called by muse, mutect2, varscan2
- CCDC105 | c.879C>T p.C293= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV52963298; called by mutect2, varscan2
- CCDC150 | c.1167T>C p.F389= | Silent (SNP) | VAF 48/59 reads (81%) | catalogued as COSV55873624; called by muse, mutect2, varscan2
- CCDC60 | c.654G>A p.K218= | Silent (SNP) | VAF 18/29 reads (62%) | catalogued as rs117667301, COSV59542626; called by muse, mutect2, varscan2
- CCR2 | c.408C>T p.I136= | Silent (SNP) | VAF 117/294 reads (40%) | catalogued as rs781525332, COSV52748286; called by mutect2, varscan2
- CCR8 | c.675G>A p.L225= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV58337064; called by mutect2, varscan2
- CDH7 | c.285C>T p.F95= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV59884426, COSV59896137; called by muse, mutect2, varscan2
- CDH8 | c.1260C>T p.I420= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV54860822; called by mutect2, varscan2
- CEMIP | c.1647G>A p.Q549= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as rs1294053397, COSV54990753; called by muse, mutect2, varscan2
- CENPU | c.1251G>A p.Q417= | Silent (SNP) | VAF 190/311 reads (61%) | catalogued as COSV55657172; called by muse, mutect2, varscan2
- CILP | c.2088G>A p.V696= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as COSV56023324; called by muse, mutect2, varscan2
- CKAP5 | c.2961C>T p.L987= | Silent (SNP) | VAF 32/60 reads (53%) | catalogued as COSV56366435; called by mutect2, varscan2
- CLCN3 | c.1215C>T p.A405= | Silent (SNP) | VAF 42/129 reads (33%) | catalogued as COSV61626244; called by muse, mutect2, varscan2
- CLCN4 | c.1968C>T p.L656= | Silent (SNP) | VAF 18/18 reads (100%) | catalogued as rs370979983, COSV66465246; called by mutect2, varscan2
- CR2 | c.480C>T p.I160= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV65506208; called by muse, mutect2, varscan2
- CSMD1 | c.9924C>T p.F3308= (on ENST00000520002; = p.F3307= on NM_033225.6) | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs753525110, COSV59294648; called by muse, mutect2, varscan2
- CUL9 | c.774C>T p.S258= | Silent (SNP) | VAF 78/138 reads (57%) | catalogued as COSV52727607; called by muse, mutect2, varscan2
- CUX2 | c.3120C>T p.I1040= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1405869296, COSV55629406; called by mutect2, varscan2
- CYP2A7 | c.1128G>A p.K376= | Silent (SNP) | VAF 52/54 reads (96%) | catalogued as COSV52500185; called by muse, mutect2, varscan2
- DAGLA | c.2364C>T p.S788= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV57195360; called by muse, mutect2, varscan2
- DDX60 | c.1879T>C p.L627= | Silent (SNP) | VAF 59/90 reads (66%) | catalogued as COSV67096283; called by muse, mutect2, varscan2
- DLGAP1 | c.2388C>T p.F796= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV59797623, COSV59834307; called by muse, mutect2, varscan2
- DNAH17 | c.358C>T p.L120= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV67752360; called by muse, mutect2, varscan2
- DNAH5 | c.12144C>T p.L4048= | Silent (SNP) | VAF 32/164 reads (20%) | catalogued as COSV54205794; called by muse, mutect2, varscan2
- DNAH9 | c.1317G>A p.L439= | Silent (SNP) | VAF 45/89 reads (51%) | catalogued as rs147288160; called by muse, mutect2, varscan2
- DNAJC21 | c.627C>T p.F209= | Silent (SNP) | VAF 36/40 reads (90%) | catalogued as rs753129989, COSV57759942; called by mutect2, varscan2
- DOP1B | c.1773C>T p.I591= | Silent (SNP) | VAF 48/100 reads (48%) | catalogued as rs141312847; called by mutect2, varscan2
- EBF1 | c.219C>T p.A73= | Silent (SNP) | VAF 16/20 reads (80%) | catalogued as COSV58174627; called by muse, mutect2, varscan2
- EEF2KMT | c.978G>C p.L326= | Silent (SNP) | VAF 60/147 reads (41%) | catalogued as COSV52157232; called by muse, mutect2, varscan2
- EMILIN3 | c.396C>T p.H132= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as COSV60035776; called by muse, mutect2, varscan2
- ENPEP | c.178C>T p.L60= | Silent (SNP) | VAF 61/145 reads (42%) | catalogued as rs1045133585, COSV54449468; called by muse, mutect2, varscan2
- EPPK1 | c.2377C>T p.L793= | Silent (SNP) | VAF 65/82 reads (79%) | catalogued as COSV73261057; called by muse, mutect2, varscan2
- ERLEC1 | c.75G>A p.L25= | Silent (SNP) | VAF 18/22 reads (82%) | catalogued as rs1039784794, COSV51751839; called by mutect2, varscan2
- FAM120C | c.1251C>T p.S417= | Silent (SNP) | VAF 63/63 reads (100%) | catalogued as COSV60258755; called by muse, mutect2, varscan2
- FAM71D | c.507C>T p.A169= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV61295205; called by muse, varscan2
- FCN3 | c.216C>T p.G72= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV54641036; called by muse, mutect2, varscan2
- FER1L5 | c.6192G>A p.K2064= (on ENST00000623019; = p.K2028= on NM_001293083.2) | Silent (SNP) | VAF 130/143 reads (91%) | catalogued as rs772399905, COSV53841379; called by muse, mutect2, varscan2
- FER1L6 | c.942C>T p.F314= | Silent (SNP) | VAF 87/140 reads (62%) | catalogued as COSV67549491; called by muse, mutect2, varscan2
- GALR1 | c.639C>T p.L213= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV100231721; called by muse, mutect2, varscan2
- GDF5 | c.222C>T p.A74= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV65500670; called by muse, mutect2, varscan2
- HCK | c.1356C>T p.T452= | Silent (SNP) | VAF 84/180 reads (47%) | catalogued as COSV52941870; called by muse, mutect2, varscan2
- HINFP | c.1098G>A p.K366= | Silent (SNP) | VAF 65/72 reads (90%) | catalogued as COSV63431869; called by muse, mutect2, varscan2
- HPS5 | c.3303C>T p.I1101= (on ENST00000349215 / NM_181507.2; = p.I987= on NM_007216.4) | Silent (SNP) | VAF 52/134 reads (39%) | catalogued as COSV61687377; called by muse, mutect2, varscan2
- HTR1B | c.234G>A p.R78= | Silent (SNP) | VAF 84/88 reads (95%) | catalogued as COSV64051359; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1512G>A p.V504= | Silent (SNP) | VAF 22/24 reads (92%) | catalogued as COSV61152097; called by mutect2, varscan2
- IMPA2 | c.291G>A p.T97= | Silent (SNP) | VAF 38/123 reads (31%) | catalogued as rs748365198, COSV52319285, COSV52319358; called by mutect2, varscan2
- KCNH2 | c.2052C>T p.I684= | Silent (SNP) | VAF 52/53 reads (98%) | catalogued as COSV51135107; called by muse, mutect2, varscan2
- KCNK13 | c.468C>T p.I156= | Silent (SNP) | VAF 45/107 reads (42%) | catalogued as COSV56411637; called by muse, mutect2, varscan2
- KCNT2 | c.426G>A p.L142= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV54064390; called by muse, mutect2, varscan2
- KIAA1109 | c.13410C>T p.T4470= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV99149523; called by muse, mutect2, varscan2
- KIAA1958 | c.2142C>T p.C714= | Silent (SNP) | VAF 26/37 reads (70%) | catalogued as rs375882540; called by muse, mutect2, varscan2
- KLHL25 | c.1485C>T p.F495= | Silent (SNP) | VAF 46/122 reads (38%) | catalogued as COSV61994793; called by mutect2, varscan2
- KLK4 | c.306C>T p.S102= | Silent (SNP) | VAF 38/40 reads (95%) | catalogued as rs866842262, COSV100133585, COSV60676125; called by muse, varscan2
- KRT9 | c.1863C>T p.S621= | Silent (SNP) | VAF 44/79 reads (56%) | catalogued as rs771175009, COSV55852426; called by muse, mutect2, varscan2
- LAMC1 | c.456C>T p.F152= | Silent (SNP) | VAF 112/288 reads (39%) | catalogued as COSV99279249; called by muse, mutect2, varscan2
- LAP3 | c.1257C>T p.F419= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs766343900, COSV56899466; called by mutect2, varscan2
- LCE3E | c.33A>G p.Q11= | Silent (SNP) | VAF 49/120 reads (41%) | catalogued as rs777621256, COSV64231683; called by muse, mutect2, varscan2
- LCT | c.2193G>A p.G731= | Silent (SNP) | VAF 76/83 reads (92%) | catalogued as COSV51547185; called by muse, mutect2, varscan2
- MAGEB6B | c.937C>T p.L313= | Silent (SNP) | VAF 71/76 reads (93%) | called by muse, mutect2, varscan2
- MAP7 | c.804G>A p.S268= | Silent (SNP) | VAF 41/44 reads (93%) | catalogued as COSV63418925; called by mutect2, varscan2
- MASP2 | c.873C>T p.I291= | Silent (SNP) | VAF 67/102 reads (66%) | catalogued as COSV68896414; called by muse, mutect2, varscan2
- MB21D2 | c.321C>T p.V107= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV66662842; called by muse, mutect2, varscan2
- MBL2 | c.549C>T p.F183= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV64758217; called by muse, mutect2, varscan2
- MEI1 | c.1101C>T p.I367= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs199669858; called by mutect2, varscan2
- MGAT4B | c.372C>T p.A124= | Silent (SNP) | VAF 16/23 reads (70%) | catalogued as rs749269349, COSV52977512; called by muse, mutect2, varscan2
- MINAR1 | c.882C>T p.P294= | Silent (SNP) | VAF 52/121 reads (43%) | catalogued as COSV59582196; called by muse, mutect2, varscan2
- MKKS | c.228C>T p.I76= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV61398101; called by muse, mutect2, varscan2
- MLIP | c.1152T>A p.P384= | Silent (SNP) | VAF 228/562 reads (41%) | catalogued as COSV51428585; called by muse, varscan2
- MOV10L1 | c.459G>A p.K153= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV53169866; called by muse, mutect2, varscan2
- MTSS1 | c.423C>A p.S141= | Silent (SNP) | VAF 64/408 reads (16%) | catalogued as COSV61496337; called by mutect2, varscan2
- MYO9B | c.351C>T p.T117= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs771091067, COSV68278411; called by muse, mutect2, varscan2
- NAT10 | c.2661C>T p.P887= | Silent (SNP) | VAF 70/150 reads (47%) | catalogued as rs142246385; called by muse, varscan2
- NEURL4 | c.3564C>T p.S1188= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV59748816; called by muse, mutect2, varscan2
- NIBAN3 | c.1815G>A p.L605= | Silent (SNP) | VAF 60/120 reads (50%) | catalogued as COSV56307464; called by muse, varscan2
- NOC4L | c.579C>T p.A193= | Silent (SNP) | VAF 40/69 reads (58%) | catalogued as COSV57957897; called by muse, mutect2, varscan2
- NOS1 | c.375C>T p.P125= | Silent (SNP) | VAF 32/49 reads (65%) | catalogued as rs1461666335, COSV57610470; called by muse, mutect2, varscan2
- NPAP1 | c.376C>T p.L126= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as COSV61506051; called by muse, mutect2, varscan2
- NSMAF | c.933C>T p.S311= | Silent (SNP) | VAF 36/129 reads (28%) | catalogued as COSV50685728; called by muse, varscan2
- NSMAF | c.897G>A p.E299= | Silent (SNP) | VAF 42/72 reads (58%) | catalogued as COSV50685753, COSV50698739; called by muse, varscan2
- NSUN2 | c.228C>T p.A76= | Silent (SNP) | VAF 105/174 reads (60%) | catalogued as COSV52953651; called by muse, mutect2, varscan2
- NT5C1B | c.1167G>A p.V389= (on ENST00000359846 / NM_001199086.2; = p.V329= on NM_033253.4) | Silent (SNP) | VAF 45/55 reads (82%) | catalogued as COSV58395386; called by muse, varscan2
- NTSR2 | c.798C>T p.I266= | Silent (SNP) | VAF 65/74 reads (88%) | catalogued as rs17853769, COSV60990864; called by muse, mutect2, varscan2
- NUP210 | c.4527C>T p.S1509= | Silent (SNP) | VAF 48/109 reads (44%) | catalogued as COSV54405068; called by muse, varscan2
- NYNRIN | c.3777C>T p.S1259= | Silent (SNP) | VAF 24/38 reads (63%) | catalogued as COSV66841976; called by muse, mutect2, varscan2
- OR10P1 | c.522C>T p.I174= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV59006921; called by mutect2, varscan2
- OR10R2 | c.954A>G p.Q318= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV63768717; called by muse, mutect2, varscan2
- OR11H12 | c.450C>T p.I150= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV73569136; called by mutect2, varscan2
- OR12D3 | c.510G>A p.Q170= | Silent (SNP) | VAF 36/63 reads (57%) | catalogued as COSV65827308; called by muse, mutect2, varscan2
- OR5R1 | c.681G>A p.R227= | Silent (SNP) | VAF 26/49 reads (53%) | catalogued as COSV56572011; called by muse, mutect2, varscan2
- OR6F1 | c.300G>A p.Q100= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as rs752777776, COSV57467493; called by muse, mutect2, varscan2
- OR6N1 | c.927G>A p.G309= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV58647971; called by muse, varscan2
- OR7G2 | c.333G>A p.R111= | Silent (SNP) | VAF 45/93 reads (48%) | catalogued as COSV59687732; called by muse, mutect2, varscan2
- OR8B3 | c.639C>T p.T213= | Silent (SNP) | VAF 49/54 reads (91%) | catalogued as COSV63541576; called by muse, mutect2, varscan2
- PACS1 | c.2493C>T p.P831= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs756717910, COSV100270165, COSV57697332; called by muse, mutect2, varscan2
- PARD3 | c.963T>C p.N321= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV60748198; called by muse, mutect2, varscan2
- PAX5 | c.945C>T p.Y315= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV63906591; called by mutect2, varscan2
- PCDHB1 | c.351C>T p.F117= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV60629587; called by muse, mutect2, varscan2
- PIK3C2B | c.1116C>T p.L372= | Silent (SNP) | VAF 83/144 reads (58%) | catalogued as rs116461271, COSV65803545; called by muse, mutect2, varscan2
- PIK3C2B | c.483C>T p.P161= | Silent (SNP) | VAF 71/115 reads (62%) | catalogued as COSV65803550; called by muse, mutect2, varscan2
- PLEKHH3 | c.1491C>T p.H497= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV52217317; called by mutect2, varscan2
- PNPLA6 | c.984C>T p.F328= (on ENST00000414982 / NM_001166111.2; = p.F280= on NM_006702.5) | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV55374725; called by muse, mutect2, varscan2
- POMT1 | c.1311C>T p.S437= | Silent (SNP) | VAF 47/83 reads (57%) | catalogued as COSV61225688; called by muse, mutect2, varscan2
- PROX1 | c.2085C>T p.A695= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV54778035; called by muse, mutect2, varscan2
- PRTG | c.2616C>T p.H872= | Silent (SNP) | VAF 56/112 reads (50%) | catalogued as COSV66837604; called by muse, mutect2, varscan2
- PSME3 | c.426C>T p.L142= | Silent (SNP) | VAF 72/143 reads (50%) | catalogued as COSV53198777; called by muse, mutect2, varscan2
- PTPRT | c.1302G>A p.Q434= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as COSV61974585, COSV62036887; called by muse, mutect2, varscan2
- RAB35 | c.498G>A p.E166= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV99984549; called by muse, varscan2
- RASEF | c.1194C>T p.G398= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV64586720; called by muse, mutect2, varscan2
- RERGL | c.606G>A p.R202= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV57461035; called by muse, mutect2, varscan2
- RNF123 | c.1092C>T p.L364= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV59686236; called by muse, varscan2
- ROS1 | c.1485C>T p.P495= | Silent (SNP) | VAF 34/37 reads (92%) | catalogued as COSV63853862; called by muse, mutect2, varscan2
- RPL17 | c.513C>T p.S171= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV100271544; called by muse, mutect2, varscan2
- RPL29 | c.160C>T p.L54= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as rs1280325957, COSV99587575; called by muse, mutect2, varscan2
- RPL29 | c.159C>T p.G53= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV99587578; called by muse, mutect2, varscan2
- RUNX1 | c.601C>T p.L201= (on ENST00000344691 / NM_001001890.3; = p.L228= on NM_001754.5) | Silent (SNP) | VAF 63/136 reads (46%) | catalogued as rs1446346250, COSV55873618; called by muse, mutect2, varscan2
- SALL1 | c.2325C>T p.F775= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as rs769521342, COSV51756087; called by mutect2, varscan2
- SERPINA3 | c.162G>A p.V54= | Silent (SNP) | VAF 51/112 reads (46%) | catalogued as COSV67585845; called by muse, mutect2, varscan2
- SGCB | c.714C>T p.T238= | Silent (SNP) | VAF 85/161 reads (53%) | catalogued as COSV67340848; called by muse, mutect2, varscan2
- SHROOM4 | c.627G>A p.E209= | Silent (SNP) | VAF 18/19 reads (95%) | catalogued as COSV56787777; called by muse, mutect2, varscan2
- SIN3B | c.336T>C p.I112= | Silent (SNP) | VAF 43/120 reads (36%) | catalogued as COSV56132458; called by muse, mutect2, varscan2
- SLC22A25 | c.639C>T p.I213= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV100123487; called by mutect2, varscan2
- SLC44A5 | c.513G>A p.A171= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as rs762534368, COSV63762599; called by mutect2, varscan2
- SLC5A12 | c.300C>T p.L100= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV54820555; called by muse, mutect2, varscan2
- SLC7A2 | c.357C>T p.L119= (on ENST00000494857 / NM_001370338.1; = p.L159= on NM_003046.6) | Silent (SNP) | VAF 49/91 reads (54%) | catalogued as rs974225804, COSV50250785; called by muse, mutect2, varscan2
- SLC8A3 | c.1657C>T p.L553= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV63520431; called by muse, varscan2
- SMTNL1 | c.1320G>A p.Q440= (on ENST00000399154; = p.Q477= on NM_001105565.2) | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs1234287953, COSV54702790; called by muse, mutect2, varscan2
- SNAP47 | c.948G>A p.R316= | Silent (SNP) | VAF 66/125 reads (53%) | catalogued as COSV59917555; called by muse, mutect2, varscan2
- STAB2 | c.5658G>A p.L1886= | Silent (SNP) | VAF 23/36 reads (64%) | catalogued as rs765937109, COSV66334210; called by muse, varscan2
- SYT13 | c.912C>T p.L304= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV50073182; called by muse, mutect2, varscan2
- SYT16 | c.1677T>G p.R559= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV70856118; called by muse, mutect2, varscan2
- TCF25 | c.1929C>T p.N643= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as rs1386615575, COSV54526445; called by muse, mutect2, varscan2
- TEP1 | c.1149G>A p.R383= | Silent (SNP) | VAF 51/116 reads (44%) | catalogued as rs1291627175, COSV52991229; called by muse, mutect2, varscan2
- TEX14 | c.2010G>A p.L670= (on ENST00000240361 / NM_001201457.2; = p.L664= on NM_031272.5) | Silent (SNP) | VAF 46/113 reads (41%) | catalogued as COSV53614948; called by muse, mutect2, varscan2
- TGIF1 | c.240G>A p.K80= (on ENST00000330513 / NM_001374396.1; = p.K100= on NM_003244.4) | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV57907085; called by muse, mutect2, varscan2
- TLE4 | c.348G>A p.R116= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV54630228, COSV54633264; called by muse, mutect2, varscan2
- TMBIM6 | c.60C>T p.T20= | Silent (SNP) | VAF 32/59 reads (54%) | catalogued as COSV57279191; called by muse, mutect2, varscan2
- TMC2 | c.2241C>T p.F747= | Silent (SNP) | VAF 45/85 reads (53%) | catalogued as rs1473807085, COSV62651756; called by muse, mutect2, varscan2
- TMEM184A | c.1227C>T p.P409= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs779216994, COSV52472894; called by muse, mutect2, varscan2
- TNRC6C | c.144G>T p.A48= | Silent (SNP) | VAF 56/131 reads (43%) | catalogued as COSV56943452; called by muse, mutect2, varscan2
- TRBC2 | c.441C>T p.I147= | Silent (SNP) | VAF 58/62 reads (94%) | called by muse, mutect2, varscan2
- TRIB2 | c.90A>T p.I30= | Silent (SNP) | VAF 38/46 reads (83%) | catalogued as COSV50224856; called by mutect2, varscan2
- TRIM21 | c.132G>A p.G44= | Silent (SNP) | VAF 49/134 reads (37%) | catalogued as COSV54343727; called by muse, mutect2, varscan2
- TSHZ2 | c.1104C>T p.Y368= | Silent (SNP) | VAF 40/144 reads (28%) | catalogued as rs780372484, COSV61588063; called by muse, mutect2, varscan2
- TTN | c.18210C>T p.I6070= (on ENST00000591111; = p.I5143= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/21 reads (86%) | catalogued as rs936677884, COSV59977700; called by mutect2, varscan2
- VPS13B | c.2058G>A p.R686= | Silent (SNP) | VAF 55/212 reads (26%) | catalogued as COSV100661331; called by muse, mutect2, varscan2
- VSIG10 | c.798C>T p.I266= | Silent (SNP) | VAF 40/59 reads (68%) | catalogued as rs371816744; called by mutect2, varscan2
- VTN | c.504G>A p.K168= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV56873275; called by muse, mutect2, varscan2
- WASHC2C | c.3285C>T p.A1095= (on ENST00000336378; = p.A1074= on NM_015262.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- WDR48 | c.1833T>C p.S611= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV56531426; called by muse, mutect2, varscan2
- XIRP2 | c.7776T>A p.A2592= (on ENST00000628543; = p.A2767= on NM_152381.6) | Silent (SNP) | VAF 14/16 reads (88%) | catalogued as COSV54693793; called by muse, mutect2, varscan2
- ZBED9 | c.837C>T p.I279= | Silent (SNP) | VAF 66/168 reads (39%) | catalogued as COSV71729306; called by muse, mutect2, varscan2
- ZBTB4 | c.2178C>T p.H726= | Silent (SNP) | VAF 30/59 reads (51%) | catalogued as rs1291054850, COSV100262969; called by muse, mutect2, varscan2
- ZNF208 | c.813C>T p.I271= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs267605387, COSV68103689; called by muse, varscan2
- ZNF274 | c.525C>A p.P175= (on ENST00000610905; = p.P70= on NM_016324.3) | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as COSV100465263, COSV58763928; called by mutect2, varscan2
- ZNF300 | c.12C>T p.S4= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV51033957; called by muse, mutect2
- ZNF436 | c.1104G>A p.G368= | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as COSV58358384; called by muse, mutect2, varscan2
- ZNF662 | c.556C>T p.L186= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV60241451; called by muse, mutect2, varscan2
- ARPP19P2 | n.155G>A | RNA (SNP) | VAF 54/60 reads (90%) | catalogued as rs754124555; called by mutect2, varscan2
- DEFB119 | c.62-934G>A | Intron (SNP) | VAF 32/77 reads (42%) | catalogued as COSV53619840; called by muse, varscan2
- DLG2 | c.205-65774G>A | Intron (SNP) | VAF 61/64 reads (95%) | catalogued as COSV99713686; called by muse, varscan2
- HDAC9 | c.2577+29T>A | Intron (SNP) | VAF 10/34 reads (29%) | called by mutect2, varscan2
- MAGEC3 | c.1124-124G>A | Intron (SNP) | VAF 44/46 reads (96%) | catalogued as COSV100025085; called by muse, varscan2
- MICD | chr6:29975306 G>C | 5'Flank (SNP) | VAF 10/27 reads (37%) | catalogued as rs779497833; called by muse, mutect2, varscan2
- MIR506 | n.39C>T | RNA (SNP) | VAF 22/24 reads (92%) | catalogued as rs1557101398; called by mutect2, varscan2
- NR5A2 | c.65-927C>T | Intron (SNP) | VAF 26/67 reads (39%) | called by muse, mutect2, varscan2
- SNORD116-29 | n.25G>A | RNA (SNP) | VAF 25/40 reads (63%) | called by muse, mutect2, varscan2
